Gene-level copy-number profile of tumor specimen TCGA-VQ-A8E0-01A from TCGA case TCGA-VQ-A8E0, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.0 years (24,848 days).
Specimen TCGA-VQ-A8E0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.7a443d97-29db-4999-85c0-4e4cf60ebc65.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8E0-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83d07cf8-7275-4f8e-87b0-34bec1bda442

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 1,257; copy number 2: 26,861; copy number 3: 17,552; copy number 4: 7,747; copy number 5: 4,481; copy number 6: 821; copy number 7: 213; copy number 8: 288; copy number 9: 84; copy number 10: 94; copy number 11: 39; copy number 12: 137; copy number 14: 24; copy number 15: 11; copy number 16: 150; copy number 18: 2; copy number 19: 1; copy number 25: 5; copy number 27: 12; copy number 33: 2; copy number 86: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8E0-01A-11D-A40Z-01): tumor purity 0.46, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–1,012,934, 13 genes: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,326 genes in 75 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,429,881–11,262,551, 28 genes, copy number 5 (within-gene range 2–5): AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1, PEX14, AL139423.2, RN7SL614P, CASZ1, AL139423.1, HSPE1P24, C1orf127, CFL1P6, TARDBP, AL109811.3, MASP2, AL109811.2, SRM, EXOSC10, AL109811.1, EXOSC10-AS1, MTOR, MTOR-AS1, RNU6-537P, ANGPTL7, RNU6-291P, RPL39P6.
- chr1:89,788,914–91,404,856, 25 genes, copy number 6: AC099568.1, AC099568.2, LRRC8D, AL391497.1, RN7SKP272, GEMIN8P4, ZNF326, AL161797.1, AC098656.1, RNU6-695P, AL627316.1, LINC02787, SNORD3G, BARHL2, AC092805.1, LINC02609, LINC02788, LINC01763, AC091614.1, PHKA1P1, ZNF644, RPL5P6, HFM1, Y_RNA, FEN1P1.
- chr1:185,226,808–185,520,986, 13 genes, copy number 7: RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2.
- chr3:61,561,569–65,193,509, 45 genes, copy number 5: PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040.
- chr3:68,731,766–69,593,121, 14 genes, copy number 5: TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1.
- chr3:93,843,764–109,977,767, 211 genes, copy number 5 (broad region; genes not listed).
- chr3:140,449,435–156,037,647, 264 genes, copy number 5–8 (broad region; genes not listed).
- chr3:161,083,883–166,844,956, 42 genes, copy number 5: B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2.
- chr3:172,505,508–188,003,990, 297 genes, copy number 5–8 (broad region; genes not listed).
- chr4:1,692,731–2,242,276, 16 genes, copy number 5 (within-gene range 2–5): SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2.
- chr5:10,137,138–10,472,029, 19 genes, copy number 6 (within-gene range 4–6): AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L.
- chr5:14,872,332–50,443,248, 445 genes, copy number 5 (broad region; genes not listed).
- chr5:115,267,190–116,085,416, 26 genes, copy number 6 (within-gene range 4–6): CCDC112, HMGN1P15, CTNNA1P1, AK3P4, AC008628.2, AC008628.1, CCT5P1, FEM1C, TICAM2, TMED7-TICAM2, AC010226.1, TMED7, AC008549.2, AC008549.1, H3P24, RNU2-49P, CDO1, ATG12, AP3S1, LINCADL, LVRN, DDX43P1, ARL14EPL, AC034236.1, AC034236.3, AC034236.2.
- chr5:123,236,079–147,510,068, 558 genes, copy number 5 (broad region; genes not listed).
- chr5:147,870,682–181,342,213, 660 genes, copy number 5 (broad region; genes not listed).
- chr6:75,084,326–75,593,145, 15 genes, copy number 5 (within-gene range 4–5): COL12A1, COX7A2, TMEM30A, TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P.
- chr7:46,261,064–62,275,678, 242 genes, copy number 5–7 (broad region; genes not listed).
- chr7:64,870,172–66,995,587, 79 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:85,421,122–87,480,435, 18 genes, copy number 6 (within-gene range 2–6): LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4.
- chr7:91,311,368–103,152,325, 338 genes, copy number 6–27 (broad region; genes not listed).
- chr7:105,014,190–105,876,604, 16 genes, copy number 7 (within-gene range 2–7): KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1.
- chr8:63,013,068–65,771,261, 39 genes, copy number 6 (within-gene range 3–6): AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1.
- chr8:67,849,044–71,592,025, 52 genes, copy number 5–7 (within-gene range 4–7): NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2.
- chr8:120,380,761–124,728,473, 77 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:130,935,409–133,947,335, 40 genes, copy number 5–7: AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3.
- chr11:167,784–727,727, 50 genes, copy number 7: BET1L, ODF3, AC069287.2, RIC8A, MIR6743, SIRT3, PSMD13, AC136475.10, NLRP6, AC136475.3, PGGHG, IFITM5, AC136475.6, IFITM2, AC136475.2, IFITM1, AC136475.1, IFITM3, AC136475.4, AC136475.8, AC136475.7, AC136475.5, AC136475.9, B4GALNT4, PKP3, SIGIRR, ANO9, RN7SL838P, PTDSS2, AC138230.1, RNH1, AC137894.4, AC137894.1, HRAS, LRRC56, LMNTD2, LMNTD2-AS1, RASSF7, MIR210HG, MIR210, PHRF1, IRF7, CDHR5, SCT, DRD4, DEAF1, AC131934.1, EPS8L2, TMEM80, AP006621.4.
- chr11:26,285,578–34,431,649, 124 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:17,710,934–22,008,880, 57 genes, copy number 5–7: Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1.
- chr12:58,544,124–72,670,758, 251 genes, copy number 5–15 (within-gene range 2–15) (broad region; genes not listed).
- chr14:18,333,726–49,374,383, 778 genes, copy number 5–9 (broad region; genes not listed).
- chr14:101,948,347–104,052,667, 77 genes, copy number 5 (broad region; genes not listed).
- chr15:19,878,555–30,883,231, 425 genes, copy number 6 (broad region; genes not listed).
- chr16:2,883,213–3,224,779, 36 genes, copy number 8: FLYWCH2, FLYWCH1, RPL23AP86, AC004034.1, KREMEN2, PKMYT1, PAQR4, AC004233.3, LINC00514, AC004233.1, AC004233.4, AC004233.2, CLDN9, CLDN6, TNFRSF12A, HCFC1R1, THOC6, BICDL2, AC108134.1, MMP25-AS1, MMP25, IL32, RNU1-125P, AC108134.3, RNU1-22P, ZSCAN10, ZNF213-AS1, AC108134.4, ZNF205, ZNF213, CASP16P, AC108134.2, AJ003147.1, AJ003147.2, OR1F1, OR1F2P.
- chr16:29,595,130–32,636,045, 231 genes, copy number 8 (broad region; genes not listed).
- chr16:35,446,898–35,912,516, 44 genes, copy number 6: ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr16:67,481,314–70,801,160, 163 genes, copy number 5–7 (broad region; genes not listed).
- chr18:20,946,906–37,992,413, 268 genes, copy number 5 (broad region; genes not listed).
- chr19:35,704,558–36,045,972, 34 genes, copy number 5 (within-gene range 2–5): ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4, PSENEN, AD000671.1, AD000671.3, LIN37, AC002398.2, HSPB6, PROSER3, AC002398.1, ARHGAP33, LINC01529, PRODH2, NPHS1, KIRREL2, APLP1, RN7SL402P, NFKBID, AD000864.1, HCST, TYROBP, LRFN3, AF038458.3, AF038458.1, AF038458.2, SDHAF1, SYNE4, AC002116.1, ALKBH6, AC002116.2, CLIP3.
- chr20:25,452,697–30,312,480, 50 genes, copy number 5–25: NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A, FRG1CP, FRG1DP, 5_8S_rRNA, DUX4L32, PCMTD1P7, DUX4L33, DUX4L34, FRG2EP, RARRES2P11, AGGF1P10, DUX4L35, FRG1EP, FAM242B, Y_RNA, CFTRP2, 5_8S_rRNA, CDC27P3, RNA5SP532, DUX4L37, CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA.
- chr20:35,002,404–35,412,031, 16 genes, copy number 5 (within-gene range 3–5): TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1.

Autosomal genes at a single copy (total copy number 1): 1,257. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
